Somatic mutation profile of tumor specimen 0DIDTW from CCDI case PBBVRK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 5.7 years (2,096 days).
Specimen 0DIDTW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 159a3444-6780-4654-b734-8ab7864b2e9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIDS5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4aa20d53-90aa-4175-98a4-ae6bc5ea9f23

The open-access MAF lists 45 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 13, Silent 10, Nonsense Mutation 6, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 97/302 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CAMKV | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 145/689 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV56556748; called by muse, mutect2, varscan2
- CDH23 | c.5920G>A p.A1974T | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs1019788678; called by muse, mutect2, varscan2
- CLIC3 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 23/498 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as rs1459329791, COSV65406638; called by muse, mutect2
- MAP7D1 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 124/418 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as rs1335587137; called by muse, mutect2, varscan2
- NALCN | c.4690G>T p.E1564* | Nonsense Mutation (SNP) | VAF 120/708 reads (17%) | catalogued as COSV51954234, COSV99218717; called by muse, mutect2, varscan2
- NLGN1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 95/451 reads (21%) | catalogued as rs1403799923; called by muse, mutect2, varscan2
- ARMC9 | c.1780C>A p.H594N | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BEND4 | c.1526C>A p.S509* | Nonsense Mutation (SNP) | VAF 99/426 reads (23%) | called by muse, mutect2, varscan2
- CAMTA1 | c.2501G>T p.S834I | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- DNAH14 | c.7018C>G p.L2340V (on ENST00000445597; = p.L2993V on NM_001367479.1) | Missense Mutation (SNP) | VAF 107/327 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- GON4L | c.3292C>T p.P1098S | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- GRIK2 | c.1317G>C p.L439F | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MDGA1 | c.2390G>C p.G797A | Missense Mutation (SNP) | VAF 108/383 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC17 | c.12374C>A p.S4125* | Nonsense Mutation (SNP) | VAF 95/514 reads (18%) | called by mutect2, varscan2
- OPTC | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PPEF1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 137/256 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRKDC | c.12371G>A p.W4124* | Nonsense Mutation (SNP) | VAF 18/678 reads (3%) | called by muse, mutect2
- RB1CC1 | c.2048C>A p.A683E | Missense Mutation (SNP) | VAF 93/526 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- STH | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 65/384 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ZBTB16 | c.1569C>A p.C523* | Nonsense Mutation (SNP) | VAF 34/642 reads (5%) | called by muse, mutect2
- CHMP7 | c.1095G>T p.L365= | Silent (SNP) | VAF 70/397 reads (18%) | called by muse, mutect2, varscan2
- DNAJC30 | c.441C>T p.T147= | Silent (SNP) | VAF 154/641 reads (24%) | called by muse, mutect2, varscan2
- ECHDC1 | c.717T>G p.T239= (on ENST00000531967 / NM_001139510.1; = p.T233= on NM_001002030.2) | Silent (SNP) | VAF 29/444 reads (7%) | called by muse, mutect2
- FLT1 | c.1779G>T p.R593= | Silent (SNP) | VAF 130/742 reads (18%) | called by muse, mutect2, varscan2
- MBOAT1 | c.1335A>G p.A445= | Silent (SNP) | VAF 166/601 reads (28%) | called by muse, mutect2, varscan2
- NLRX1 | c.279G>T p.L93= | Silent (SNP) | VAF 107/564 reads (19%) | called by muse, mutect2, varscan2
- OR13C8 | c.552C>A p.I184= | Silent (SNP) | VAF 108/424 reads (25%) | catalogued as COSV58611065; called by muse, mutect2, varscan2
- PDZRN3 | c.2424G>T p.L808= | Silent (SNP) | VAF 86/436 reads (20%) | called by muse, mutect2, varscan2
- RBMXL3 | c.318G>A p.R106= | Silent (SNP) | VAF 48/93 reads (52%) | catalogued as COSV99067219; called by muse, mutect2, varscan2
- SALL1 | c.3327G>A p.P1109= | Silent (SNP) | VAF 109/492 reads (22%) | catalogued as rs375357921; called by muse, mutect2, varscan2
- ABCB9 | c.*8G>T | 3'UTR (SNP) | VAF 73/261 reads (28%) | catalogued as rs1472535283; called by mutect2, varscan2
- ATL2 | c.1633-68C>A | Intron (SNP) | VAF 45/158 reads (28%) | called by muse, mutect2, varscan2
- DNAJC17 | c.681+31C>T | Intron (SNP) | VAF 24/111 reads (22%) | catalogued as rs201311218; called by muse, mutect2, varscan2
- EDNRB | c.219+86T>A | Intron (SNP) | VAF 20/94 reads (21%) | catalogued as rs1368090962; called by mutect2, varscan2
- FN1 | c.6442-56G>A | Intron (SNP) | VAF 19/74 reads (26%) | catalogued as rs540468041; called by muse, mutect2, varscan2
- GPATCH2L | c.1107+178C>A | Intron (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- KDM6A | c.444-41G>C | Intron (SNP) | VAF 23/44 reads (52%) | called by muse, varscan2
- NKAPD1 | c.320+35G>T | Intron (SNP) | VAF 16/352 reads (5%) | called by muse, mutect2
- PRPF31 | c.420+49G>A | Intron (SNP) | VAF 37/187 reads (20%) | catalogued as rs749327560; called by muse, mutect2, varscan2
- SERPINE2 | c.-23+552C>T | Intron (SNP) | VAF 26/722 reads (4%) | catalogued as rs1167275846; called by muse, mutect2
- SREK1 | c.653+47T>G | Intron (SNP) | VAF 53/273 reads (19%) | called by muse, mutect2, varscan2
- TRIM67 | c.1045-12318C>A | Intron (SNP) | VAF 111/372 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.83086+48T>A | Intron (SNP) | VAF 78/296 reads (26%) | called by muse, mutect2, varscan2
- VAC14 | c.1956-66C>T | Intron (SNP) | VAF 11/62 reads (18%) | catalogued as rs1329931233; called by muse, mutect2, varscan2
